Somatic mutation profile of tumor specimen C3N-02494-01 (aliquot CPT0234790006) from CPTAC case C3N-02494, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 67.0 years (24,467 days).
Specimen C3N-02494-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09097598-0656-4370-8053-3edb37c7f5f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02494-71 (Blood Derived Normal), aliquot CPT0234910002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5cef027-32eb-4684-8469-5f42a836df98

The open-access MAF lists 321 somatic variants for this specimen: 209 protein-altering or splice-affecting, 77 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 171, Silent 77, Nonsense Mutation 18, Intron 14, Frame Shift Del 7, Splice Site 7, RNA 7, 5'Flank 5, 5'UTR 3, 3'UTR 3, Frame Shift Ins 3, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.796G>T p.G266* | Nonsense Mutation (SNP) | VAF 113/422 reads (27%) | hotspot (GDC flag); catalogued as rs1057519990, COSV52670619, COSV52672762, COSV52751844; called by muse, mutect2, varscan2
- ACSM2A | c.314G>T p.R105L (on ENST00000219054; = p.R26L on NM_001308169.2) | Missense Mutation (SNP) | VAF 95/467 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as rs371291843; called by muse, mutect2, varscan2
- ADGRB3 | c.2507C>T p.T836I | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.379); catalogued as COSV53254485; called by muse, mutect2, varscan2
- ADGRD1 | c.2474C>A p.S825* | Nonsense Mutation (SNP) | VAF 64/330 reads (19%) | catalogued as rs777694390; called by muse, mutect2, varscan2
- ADO | c.595del p.E199Kfs*138 | Frame Shift Del (DEL) | VAF 60/409 reads (15%) | catalogued as COSV65678215; called by mutect2, pindel, varscan2
- ASTN1 | c.1430C>A p.P477H | Missense Mutation (SNP) | VAF 22/290 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV56084029; called by muse, mutect2
- ASXL1 | c.4585G>A p.G1529R | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60118897, COSV60125193; called by muse, mutect2
- B3GLCT | c.1241A>G p.Y414C | Missense Mutation (SNP) | VAF 111/416 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as rs200139920; called by muse, mutect2, varscan2
- CD79B | c.587A>T p.Y196F | Missense Mutation (SNP) | VAF 161/721 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV50076054, COSV50076156, COSV50076492; called by muse, mutect2, varscan2
- CDC14C | c.353G>T p.R118L (on ENST00000428251; = p.R11L on NM_152627.3) | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1195519008; called by muse, mutect2, varscan2
- CDH8 | c.2121G>A p.M707I | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV100183771; called by muse, mutect2
- CEP164 | c.2357G>A p.R786Q | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs1296625218, COSV54044401; called by muse, mutect2
- CFAP47 | c.5371G>T p.D1791Y | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1232858623; called by muse, mutect2, varscan2
- COL1A2 | c.2553G>T p.E851D | Missense Mutation (SNP) | VAF 79/503 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1288784071; called by muse, mutect2, varscan2
- CPLX4 | c.241T>C p.Y81H | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV104409785; called by muse, mutect2, varscan2
- CSF2RB | c.2146G>A p.D716N | Missense Mutation (SNP) | VAF 120/699 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.484); catalogued as rs372927280; called by muse, mutect2, varscan2
- DHX35 | c.1499-2A>G p.X500_splice | Splice Site (SNP) | VAF 24/124 reads (19%) | catalogued as rs765430808; called by muse, mutect2, varscan2
- DPP6 | c.491C>A p.T164K (on ENST00000377770 / NM_001364500.2; = p.T102K on NM_001936.5) | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as rs761081375; called by muse, mutect2
- DTNA | c.92G>T p.R31L | Missense Mutation (SNP) | VAF 62/351 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52011011; called by muse, varscan2
- EPHA5 | c.2379C>A p.D793E | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.02); catalogued as COSV56633678; called by muse, mutect2
- ERBB3 | c.2299G>A p.D767N | Missense Mutation (SNP) | VAF 91/355 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.609); catalogued as COSV57257862; called by muse, mutect2, varscan2
- FAM83H | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 64/432 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs782246993; called by muse, mutect2, varscan2
- FGA | c.1393G>C p.V465L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV57398399; called by muse, mutect2, varscan2
- FOXP4 | c.1867C>T p.P623S (on ENST00000307972 / NM_001012426.1; = p.P610S on NM_138457.3) | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs761490426; called by muse, mutect2
- GHSR | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 59/602 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.148); catalogued as rs1417374938, COSV53837994; called by muse, mutect2, varscan2
- HTR3C | c.832C>A p.R278S | Missense Mutation (SNP) | VAF 52/554 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV59177799; called by muse, mutect2
- ITSN2 | c.509G>C p.G170A | Missense Mutation (SNP) | VAF 51/239 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1401753260; called by muse, mutect2, varscan2
- KCNJ3 | c.1352T>A p.L451Q | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV54543325; called by muse, mutect2, varscan2
- LAMA2 | c.4096C>T p.R1366C | Missense Mutation (SNP) | VAF 26/336 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as rs779253125; called by muse, mutect2
- MAGEB6B | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1305699236; called by muse, mutect2
- MALT1 | c.1396A>G p.K466E | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61934865; called by muse, mutect2
- MAP1S | c.1834G>T p.E612* | Nonsense Mutation (SNP) | VAF 24/549 reads (4%) | catalogued as COSV60725147; called by muse, mutect2
- MAP3K1 | c.1432G>T p.E478* | Nonsense Mutation (SNP) | VAF 31/149 reads (21%) | catalogued as COSV68124840; called by muse, mutect2, varscan2
- MCM7 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs200587772, COSV99053958; called by muse, mutect2, varscan2
- MYH1 | c.5258G>A p.R1753H | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as rs778397124, COSV99876445; called by muse, mutect2
- MYH1 | c.3370G>T p.E1124* | Nonsense Mutation (SNP) | VAF 63/308 reads (20%) | catalogued as COSV99876677; called by muse, mutect2, varscan2
- NEUROD6 | c.658C>G p.P220A | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.132); catalogued as COSV51772458; called by muse, mutect2, varscan2
- NSL1 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs541215299; called by muse, mutect2, varscan2
- NUTM2F | c.1901C>T p.T634M | Missense Mutation (SNP) | VAF 44/262 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs759466424, COSV99480433; called by mutect2, varscan2
- OLFML3 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.91); catalogued as rs762111882, COSV100233066, COSV57436848; called by muse, mutect2, varscan2
- OR2AT4 | c.595C>A p.P199T | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.446); catalogued as COSV59407616; called by muse, mutect2, varscan2
- OR2G3 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as COSV60683016; called by muse, mutect2, varscan2
- OR2T6 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs150463767; called by muse, mutect2, varscan2
- OR4A47 | c.520C>G p.H174D | Missense Mutation (SNP) | VAF 33/206 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV71445270; called by muse, mutect2, varscan2
- OR52K1 | c.437T>C p.I146T | Missense Mutation (SNP) | VAF 38/372 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs777471669; called by muse, mutect2
- OR5H6 | c.119A>C p.K40T (on ENST00000642105; = p.K24T on NM_001005479.2) | Missense Mutation (SNP) | VAF 58/261 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as COSV67351824; called by muse, mutect2, varscan2
- OR8J3 | c.304G>C p.G102R | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV56881903; called by muse, mutect2
- OTUD7B | c.2269G>A p.D757N | Missense Mutation (SNP) | VAF 41/266 reads (15%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.001); catalogued as rs1553771196; called by muse, mutect2, varscan2
- PCDHA8 | c.1757G>T p.G586V | Missense Mutation (SNP) | VAF 181/605 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.049); catalogued as COSV65329586; called by muse, mutect2, varscan2
- PIK3CG | c.1296G>T p.Q432H | Missense Mutation (SNP) | VAF 25/260 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.926); catalogued as COSV100782995; called by muse, mutect2, varscan2
- PXN | c.1268C>T p.P423L (on ENST00000228307 / NM_001080855.3; = p.P389L on NM_002859.4) | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV57217505; called by muse, mutect2
- RBMXL2 | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.045); catalogued as rs1390556119; called by muse, mutect2, varscan2
- RNF213 | c.10853del p.G3618Afs*22 | Frame Shift Del (DEL) | VAF 57/360 reads (16%) | catalogued as COSV100299443; called by mutect2, pindel, varscan2
- ROBO3 | c.2684C>A p.A895E | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1246835788; called by muse, mutect2, varscan2
- RSPH10B | c.2402G>A p.R801Q | Missense Mutation (SNP) | VAF 60/558 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.123); catalogued as rs377476707; called by muse, mutect2, varscan2
- RYR3 | c.6225C>A p.N2075K | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV66788575; called by muse, mutect2, varscan2
- SAMD9L | c.642G>T p.K214N | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.332); catalogued as COSV59080309; called by muse, mutect2, varscan2
- SEMA5B | c.2132G>A p.R711Q | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as rs1198569508, COSV52106365; called by muse, mutect2, varscan2
- SIGLEC1 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); catalogued as rs779069289; called by muse, mutect2, varscan2
- SLC22A24 | c.181G>C p.D61H | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV100400091; called by muse, mutect2
- SLC9B2 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as rs573118830; called by muse, varscan2
- SORCS3 | c.3483C>A p.H1161Q | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.119); catalogued as rs768149623; called by muse, mutect2
- SYNE1 | c.25402C>G p.R8468G (on ENST00000367255 / NM_182961.4; = p.R8420G on NM_033071.3) | Missense Mutation (SNP) | VAF 34/430 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs756674030, COSV54978458, COSV99569960; called by muse, mutect2
- SYTL1 | c.932C>T p.P311L (on ENST00000543823; = p.P299L on NM_032872.3) | Missense Mutation (SNP) | VAF 23/275 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1438975750; called by muse, mutect2
- TAAR5 | c.991A>G p.T331A | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1283569604; called by muse, mutect2, varscan2
- TBX22 | c.827C>A p.P276H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64785086; called by muse, mutect2, varscan2
- TENM3 | c.7672G>T p.D2558Y | Missense Mutation (SNP) | VAF 55/460 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV69306057; called by muse, mutect2, varscan2
- TEX47 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV99787281; called by muse, mutect2, varscan2
- TRIM49B | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV60320646; called by muse, mutect2
- VN1R5 | c.719A>T p.D240V | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as rs1201627282; called by muse, mutect2, varscan2
- XCR1 | c.624C>G p.I208M | Missense Mutation (SNP) | VAF 67/256 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as COSV58569138; called by muse, mutect2, varscan2
- ZBP1 | c.772C>A p.Q258K | Missense Mutation (SNP) | VAF 87/379 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59065268; called by muse, mutect2, varscan2
- ZNF429 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1457245458; called by muse, mutect2
- ZNF536 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62826032; called by muse, mutect2, varscan2
- ZNF614 | c.1246A>G p.I416V | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV54547469; called by muse, mutect2
- ZNF701 | c.1449G>T p.K483N (on ENST00000301093; = p.K417N on NM_018260.3) | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99990682; called by muse, mutect2
- ABCA10 | c.404G>A p.W135* | Nonsense Mutation (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2, varscan2
- ABCB1 | c.1032T>A p.S344R | Missense Mutation (SNP) | VAF 57/305 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ABCB9 | c.1168G>A p.V390M | Missense Mutation (SNP) | VAF 61/784 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.065); called by muse, mutect2
- ADAM12 | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 42/173 reads (24%) | called by muse, mutect2, varscan2
- ADAMTS3 | c.267A>C p.K89N | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.366); called by muse, mutect2
- ALPK1 | c.772A>T p.K258* | Nonsense Mutation (SNP) | VAF 15/140 reads (11%) | called by muse, mutect2, varscan2
- APOA4 | c.961C>G p.Q321E | Missense Mutation (SNP) | VAF 63/487 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- APOB | c.12871A>T p.K4291* | Nonsense Mutation (SNP) | VAF 29/153 reads (19%) | called by muse, mutect2, varscan2
- ARFGEF1 | c.4421G>T p.S1474I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- ASPDH | c.155C>A p.P52H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BAIAP2 | c.1474A>T p.S492C | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- C1QL2 | c.11G>C p.G4A | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); called by muse, mutect2
- CASP4 | c.137A>C p.Y46S | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CASP8AP2 | c.2158G>A p.D720N | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCT4 | c.780G>T p.M260I | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- CD300A | c.268C>A p.L90M | Missense Mutation (SNP) | VAF 40/264 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CDH10 | c.2056C>A p.L686I | Missense Mutation (SNP) | VAF 89/516 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CFAP65 | c.5144C>A p.S1715* | Nonsense Mutation (SNP) | VAF 38/154 reads (25%) | called by muse, mutect2, varscan2
- CHST1 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 55/242 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLCA1 | c.1130C>A p.A377E | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2
- CLTRN | c.57A>T p.P19= | Splice Region (SNP) | VAF 42/137 reads (31%) | called by muse, mutect2, varscan2
- COL10A1 | c.175C>G p.Q59E | Missense Mutation (SNP) | VAF 46/450 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.007); called by muse, mutect2
- COL3A1 | c.4228T>C p.Y1410H | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CROCC2 | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 33/368 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2
- CTNNA2 | c.946C>A p.L316M | Missense Mutation (SNP) | VAF 72/336 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, varscan2
- DCAF15 | c.416A>G p.Y139C | Missense Mutation (SNP) | VAF 60/340 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- DGCR8 | c.2032C>T p.Q678* | Nonsense Mutation (SNP) | VAF 15/259 reads (6%) | called by muse, mutect2
- DLGAP2 | c.1606A>T p.I536F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.206); called by muse, varscan2
- DNAH10 | c.6492G>C p.M2164I (on ENST00000409039; = p.M2103I on NM_207437.3) | Missense Mutation (SNP) | VAF 48/260 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- DNAH17 | c.7421C>A p.T2474K | Missense Mutation (SNP) | VAF 43/257 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- DNAH6 | c.7028A>C p.K2343T | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- DUOX1 | c.3094C>A p.Q1032K | Missense Mutation (SNP) | VAF 18/289 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.02); called by muse, mutect2
- ELAPOR2 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- EMP3 | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EPHA5 | c.2381T>A p.M794K | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2
- ERGIC1 | c.82+3_82+6del p.X28_splice | Splice Site (DEL) | VAF 63/307 reads (21%) | called by pindel, varscan2*
- F5 | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 37/315 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAN1 | c.2390T>C p.F797S | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- FAT3 | c.987_991dup p.Q331Rfs*31 | Frame Shift Ins (INS) | VAF 18/177 reads (10%) | called by mutect2, pindel
- FLNB | c.4249dup p.D1417Gfs*80 | Frame Shift Ins (INS) | VAF 60/281 reads (21%) | called by mutect2, pindel, varscan2
- FNDC7 | c.1517C>A p.S506Y | Missense Mutation (SNP) | VAF 35/331 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FOXJ2 | c.186C>A p.H62Q | Missense Mutation (SNP) | VAF 100/466 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- FOXP2 | c.139G>T p.V47L | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- FRG2C | c.89C>A p.T30K | Missense Mutation (SNP) | VAF 48/804 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2
- GAB4 | c.366C>A p.D122E | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GABRG2 | c.752-1G>C p.X251_splice (on ENST00000361925 / NM_001375343.1; = p.X211_splice on NM_000816.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 46/164 reads (28%) | called by muse, mutect2, varscan2
- GARRE1 | c.2027C>A p.T676K | Missense Mutation (SNP) | VAF 86/403 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- GMPR | c.165G>A p.M55I | Missense Mutation (SNP) | VAF 29/305 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- GOLGA4 | c.4094A>T p.K1365I | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GOLGA6D | c.572G>T p.S191I | Missense Mutation (SNP) | VAF 117/651 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- GOLGA6L22 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 44/585 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- GPR174 | c.834G>T p.L278F | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR31 | c.738C>A p.H246Q | Missense Mutation (SNP) | VAF 32/338 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2
- HHIPL2 | c.439G>C p.A147P | Missense Mutation (SNP) | VAF 92/457 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- HHLA1 | c.740C>A p.P247Q | Missense Mutation (SNP) | VAF 69/228 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- HS3ST4 | c.1333C>A p.Q445K | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- IGLON5 | c.361T>C p.Y121H | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by mutect2, varscan2
- JAZF1 | c.52G>T p.G18C | Missense Mutation (SNP) | VAF 77/466 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- KDM4E | c.1221C>A p.F407L | Missense Mutation (SNP) | VAF 12/343 reads (3%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); called by muse, mutect2
- KLF6 | c.803G>A p.C268Y | Missense Mutation (SNP) | VAF 36/404 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- LHX8 | c.122del p.A41Gfs*50 | Frame Shift Del (DEL) | VAF 8/63 reads (13%) | called by mutect2, varscan2
- LIN28B | c.493C>A p.P165T | Missense Mutation (SNP) | VAF 18/233 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- LNX1 | c.1937C>T p.A646V (on ENST00000263925 / NM_001126328.3; = p.A550V on NM_032622.2) | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.848); called by muse, mutect2
- LRMDA | c.346A>T p.K116* | Nonsense Mutation (SNP) | VAF 24/250 reads (10%) | called by muse, mutect2
- MAT1A | c.701A>G p.K234R | Missense Mutation (SNP) | VAF 67/576 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MPHOSPH10 | c.1063G>T p.E355* | Nonsense Mutation (SNP) | VAF 16/86 reads (19%) | called by muse, mutect2, varscan2
- MTUS2 | c.3303G>C p.E1101D (on ENST00000612955 / NM_001366650.1; = p.E80D on NM_015233.6) | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- MYLK | c.5615T>C p.V1872A | Missense Mutation (SNP) | VAF 75/412 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYLK | c.1269G>T p.Q423H | Missense Mutation (SNP) | VAF 71/344 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- MYO19 | c.1539C>G p.S513R | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- NBAS | c.277G>T p.V93L | Missense Mutation (SNP) | VAF 64/341 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- NDUFS2 | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 92/426 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NECTIN3 | c.1333G>T p.G445W | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- NOS1 | c.1242G>T p.W414C | Missense Mutation (SNP) | VAF 19/419 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NPR1 | c.2064C>G p.D688E | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- NYAP1 | c.545del p.P182Qfs*21 | Frame Shift Del (DEL) | VAF 26/176 reads (15%) | called by mutect2, pindel, varscan2
- OR4A5 | c.746T>A p.V249E | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- OR52E4 | c.758A>G p.Y253C | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR52L1 | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- OR6T1 | c.278C>A p.S93* | Nonsense Mutation (SNP) | VAF 36/285 reads (13%) | called by muse, mutect2, varscan2
- OTOGL | c.5795dup p.E1933Gfs*6 (on ENST00000547103; = p.E1924Gfs*6 on NM_173591.4 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 18/136 reads (13%) | called by mutect2, pindel, varscan2
- PKD1L2 | c.1357C>A p.L453M | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PKLR | c.1116+1G>C p.X372_splice | Splice Site (SNP) | VAF 131/614 reads (21%) | called by muse, mutect2, varscan2
- PNPLA6 | c.2095G>A p.V699M (on ENST00000414982 / NM_001166111.2; = p.V651M on NM_006702.5) | Missense Mutation (SNP) | VAF 60/539 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PPIG | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 31/264 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PPP4R3C | c.542C>A p.T181N | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- PPTC7 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 64/333 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRR12 | c.2234G>C p.G745A (on ENST00000615927; = p.G1566A on NM_020719.3) | Missense Mutation (SNP) | VAF 154/766 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PRRT2 | c.542A>G p.N181S | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PSMD14 | c.79A>T p.T27S | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- RBM10 | c.1812G>T p.Q604H | Missense Mutation (SNP) | VAF 99/375 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RDH8 | c.452G>A p.R151K (on ENST00000651512; = p.R131K on NM_015725.4) | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- REV3L | c.3231G>T p.R1077S | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2
- RHBDL3 | c.222A>T p.K74N | Missense Mutation (SNP) | VAF 63/328 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- RIMBP2 | c.362T>A p.L121H | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- RIPOR2 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RUNX2 | c.77G>T p.R26L | Missense Mutation (SNP) | VAF 138/652 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, varscan2
- SALL3 | c.2882C>T p.P961L | Missense Mutation (SNP) | VAF 48/211 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- SBK2 | c.430del p.D144Tfs*41 | Frame Shift Del (DEL) | VAF 73/446 reads (16%) | called by mutect2, pindel, varscan2
- SCARF2 | c.1222C>T p.P408S | Missense Mutation (SNP) | VAF 76/382 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SCN8A | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- SH3GLB1 | c.1065G>T p.K355N | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2
- SLC10A4 | c.141del p.L48Sfs*54 | Frame Shift Del (DEL) | VAF 40/194 reads (21%) | called by mutect2, pindel, varscan2
- SLC25A27 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 376/528 reads (71%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- SLCO1C1 | c.1733+1G>T p.X578_splice | Splice Site (SNP) | VAF 39/156 reads (25%) | called by muse, mutect2, varscan2
- SMC3 | c.2393A>G p.D798G | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SNAPC2 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.114); called by muse, mutect2
- SNX7 | c.640-1G>T p.X214_splice | Splice Site (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- SP4 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SRCIN1 | c.1613C>T p.P538L (on ENST00000621492; = p.P504L on NM_025248.3) | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- STAB2 | c.6416C>T p.A2139V | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STMND1 | c.462del p.K154Nfs*8 | Frame Shift Del (DEL) | VAF 39/187 reads (21%) | called by mutect2, pindel, varscan2
- TIMM13 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 64/322 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TIMM23 | c.106C>T p.L36= | Splice Region (SNP) | VAF 85/360 reads (24%) | called by muse, varscan2
- TMEM184B | c.1106C>T p.T369I | Missense Mutation (SNP) | VAF 111/460 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- TOM1L1 | c.219G>T p.L73F | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- TPRKB | c.527G>T p.*176Lext*12 | Nonstop Mutation (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- TRPM5 | c.2984T>C p.F995S | Missense Mutation (SNP) | VAF 29/329 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.03); called by muse, mutect2
- TULP2 | c.1276-2A>C p.X426_splice | Splice Site (SNP) | VAF 45/190 reads (24%) | called by muse, varscan2
- TYW3 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.033); called by muse, mutect2
- UBR4 | c.14353C>G p.R4785G | Missense Mutation (SNP) | VAF 54/486 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ULK3 | c.1108G>T p.A370S | Missense Mutation (SNP) | VAF 52/313 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- USP13 | c.1243G>T p.E415* | Nonsense Mutation (SNP) | VAF 74/145 reads (51%) | called by muse, mutect2, varscan2
- XIRP2 | c.754A>T p.R252* (on ENST00000628543; = p.R427* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 25/115 reads (22%) | called by muse, mutect2, varscan2
- XIRP2 | c.7182C>A p.N2394K (on ENST00000628543; = p.N2569K on NM_152381.6) | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- XIRP2 | c.8023C>A p.P2675T (on ENST00000628543; = p.P2850T on NM_152381.6) | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- YIPF7 | c.445G>T p.D149Y | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZAR1 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFYVE9 | c.3046G>A p.G1016R | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.397); called by muse, mutect2
- ZNF248 | c.429T>A p.C143* | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- ZNF529 | c.727A>T p.N243Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- ZNF850 | c.3151G>T p.G1051* | Nonsense Mutation (SNP) | VAF 50/222 reads (23%) | called by muse, mutect2, varscan2
- ZNF91 | c.3197A>G p.N1066S | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ALDH1L1 | c.2708G>A p.*903= | Silent (SNP) | VAF 12/205 reads (6%) | called by muse, mutect2
- ATP6V0A2 | c.810C>A p.I270= | Silent (SNP) | VAF 63/489 reads (13%) | called by muse, mutect2, varscan2
- BMP2K | c.2910C>G p.V970= | Silent (SNP) | VAF 30/131 reads (23%) | called by muse, mutect2, varscan2
- BRINP3 | c.1878C>T p.H626= | Silent (SNP) | VAF 33/275 reads (12%) | catalogued as COSV100818566; called by muse, mutect2, varscan2
- CABP2 | c.438A>T p.A146= | Silent (SNP) | VAF 27/235 reads (11%) | called by muse, mutect2, varscan2
- CCDC114 | c.1213C>A p.R405= | Silent (SNP) | VAF 88/376 reads (23%) | catalogued as COSV59559428; called by muse, mutect2, varscan2
- CD300LD | c.270C>T p.F90= | Silent (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- CD300LG | c.747G>A p.L249= | Silent (SNP) | VAF 23/208 reads (11%) | called by muse, mutect2, varscan2
- CEACAM18 | c.570C>A p.L190= | Silent (SNP) | VAF 54/278 reads (19%) | called by muse, mutect2, varscan2
- CHD7 | c.4944G>T p.V1648= | Silent (SNP) | VAF 18/114 reads (16%) | called by muse, mutect2, varscan2
- CHIC2 | c.99C>T p.R33= | Silent (SNP) | VAF 61/329 reads (19%) | called by muse, mutect2, varscan2
- CHRNB3 | c.405G>T p.V135= | Silent (SNP) | VAF 9/112 reads (8%) | called by muse, mutect2
- CHST13 | c.285C>T p.D95= | Silent (SNP) | VAF 82/418 reads (20%) | called by muse, mutect2, varscan2
- CMKLR1 | c.1002G>A p.L334= (on ENST00000312143 / NM_001142344.2; = p.L332= on NM_004072.3) | Silent (SNP) | VAF 22/277 reads (8%) | called by muse, mutect2
- COL22A1 | c.438C>A p.A146= | Silent (SNP) | VAF 18/204 reads (9%) | catalogued as rs557473573; called by muse, mutect2
- COL4A3 | c.711C>T p.P237= | Silent (SNP) | VAF 66/393 reads (17%) | catalogued as rs977822540; called by muse, mutect2, varscan2
- COL5A1 | c.3087G>A p.P1029= | Silent (SNP) | VAF 71/308 reads (23%) | catalogued as rs774035950, COSV65674038; ClinVar: likely benign; called by muse, mutect2, varscan2
- COX8C | c.12G>T p.L4= | Silent (SNP) | VAF 39/148 reads (26%) | called by muse, mutect2, varscan2
- CUBN | c.1131G>T p.T377= | Silent (SNP) | VAF 60/251 reads (24%) | called by muse, mutect2, varscan2
- CYTL1 | c.9G>C p.T3= | Silent (SNP) | VAF 20/177 reads (11%) | called by muse, mutect2, varscan2
- DCC | c.615G>C p.G205= | Silent (SNP) | VAF 19/209 reads (9%) | catalogued as rs772791992; called by muse, mutect2
- DHFR2 | c.252A>G p.P84= | Silent (SNP) | VAF 53/179 reads (30%) | catalogued as rs148600595, COSV58936669; called by muse, mutect2, varscan2
- DMWD | c.1773C>T p.P591= | Silent (SNP) | VAF 12/97 reads (12%) | called by muse, mutect2, varscan2
- DNAH5 | c.6735C>T p.V2245= | Silent (SNP) | VAF 65/373 reads (17%) | called by muse, mutect2, varscan2
- ELP1 | c.900G>T p.V300= | Silent (SNP) | VAF 84/354 reads (24%) | catalogued as COSV65898976; called by muse, mutect2, varscan2
- ELP4 | c.330G>T p.G110= | Silent (SNP) | VAF 9/122 reads (7%) | catalogued as COSV63358902; called by muse, mutect2
- EPHA2 | c.942C>T p.F314= | Silent (SNP) | VAF 118/594 reads (20%) | catalogued as COSV64452896; called by muse, mutect2, varscan2
- EYS | c.3216T>C p.T1072= | Silent (SNP) | VAF 8/28 reads (29%) | called by mutect2, varscan2
- FAM83B | c.846C>T p.V282= | Silent (SNP) | VAF 14/176 reads (8%) | catalogued as COSV60922009; called by muse, mutect2
- GABRD | c.168G>C p.R56= | Silent (SNP) | VAF 36/147 reads (24%) | catalogued as COSV66080885; called by muse, mutect2, varscan2
- GPA33 | c.681C>T p.A227= | Silent (SNP) | VAF 51/173 reads (29%) | catalogued as rs200023773; called by muse, mutect2, varscan2
- HEPHL1 | c.1848G>A p.V616= | Silent (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
- HOXA2 | c.135G>C p.S45= | Silent (SNP) | VAF 93/598 reads (16%) | catalogued as COSV56066115; called by muse, mutect2, varscan2
- KIF4B | c.3435G>A p.E1145= | Silent (SNP) | VAF 83/359 reads (23%) | called by muse, mutect2, varscan2
- KRT82 | c.552C>A p.S184= | Silent (SNP) | VAF 29/327 reads (9%) | called by muse, mutect2
- LAX1 | c.441C>G p.A147= | Silent (SNP) | VAF 40/136 reads (29%) | called by muse, mutect2
- LILRB3 | c.201G>A p.E67= | Silent (SNP) | VAF 54/1423 reads (4%) | called by muse, mutect2
- MLLT10 | c.171C>T p.G57= | Silent (SNP) | VAF 22/82 reads (27%) | called by muse, mutect2, varscan2
- NHSL1 | c.3471G>T p.A1157= | Silent (SNP) | VAF 50/219 reads (23%) | called by muse, mutect2, varscan2
- NMT1 | c.852G>A p.G284= | Silent (SNP) | VAF 37/162 reads (23%) | called by muse, mutect2, varscan2
- NR5A2 | c.1419C>A p.V473= (on ENST00000367362 / NM_205860.3; = p.V427= on NM_003822.5) | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as rs202153830; called by muse, mutect2, varscan2
- OR10W1 | c.429T>C p.G143= | Silent (SNP) | VAF 27/108 reads (25%) | called by muse, mutect2, varscan2
- OR52K2 | c.412C>T p.L138= | Silent (SNP) | VAF 30/341 reads (9%) | called by muse, mutect2
- OR5AR1 | c.657C>G p.T219= | Silent (SNP) | VAF 18/217 reads (8%) | called by muse, mutect2
- OR5D13 | c.475C>T p.L159= | Silent (SNP) | VAF 11/128 reads (9%) | called by muse, mutect2
- OR6C76 | c.471G>A p.L157= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as COSV60390311; called by muse, mutect2, varscan2
- OSBPL8 | c.120A>C p.P40= | Silent (SNP) | VAF 33/205 reads (16%) | catalogued as rs764940616; called by muse, mutect2, varscan2
- PAAF1 | c.312A>T p.G104= | Silent (SNP) | VAF 24/168 reads (14%) | called by muse, mutect2, varscan2
- PLK2 | c.201G>A p.P67= | Silent (SNP) | VAF 35/166 reads (21%) | catalogued as COSV57105578; called by muse, mutect2, varscan2
- PPARA | c.243G>A p.V81= | Silent (SNP) | VAF 80/443 reads (18%) | called by muse, mutect2, varscan2
- PPARGC1B | c.822C>T p.D274= | Silent (SNP) | VAF 7/106 reads (7%) | called by muse, mutect2
- PSMA1 | c.333A>G p.L111= | Silent (SNP) | VAF 19/113 reads (17%) | catalogued as rs1324299401; called by muse, mutect2, varscan2
- QPCT | c.588C>A p.I196= | Silent (SNP) | VAF 32/176 reads (18%) | called by muse, mutect2, varscan2
- RASAL3 | c.2133C>T p.L711= | Silent (SNP) | VAF 37/157 reads (24%) | called by muse, mutect2, varscan2
- RP1 | c.2343A>G p.S781= | Silent (SNP) | VAF 13/115 reads (11%) | called by muse, mutect2, varscan2
- SLC22A12 | c.111G>T p.L37= | Silent (SNP) | VAF 11/198 reads (6%) | called by muse, mutect2
- SLC4A5 | c.2115T>C p.S705= | Silent (SNP) | VAF 42/229 reads (18%) | catalogued as rs1346987835; called by muse, mutect2, varscan2
- SLIT3 | c.3765C>T p.D1255= | Silent (SNP) | VAF 46/187 reads (25%) | called by muse, mutect2, varscan2
- SMC5 | c.1425C>T p.D475= | Silent (SNP) | VAF 28/82 reads (34%) | called by muse, mutect2, varscan2
- SMURF2 | c.168G>T p.T56= | Silent (SNP) | VAF 19/117 reads (16%) | catalogued as rs1335117473; called by muse, mutect2, varscan2
- SNX32 | c.337C>A p.R113= | Silent (SNP) | VAF 44/352 reads (13%) | called by mutect2, varscan2
- SPR | c.120C>T p.S40= | Silent (SNP) | VAF 55/221 reads (25%) | catalogued as rs1450742178; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STARD9 | c.9807C>T p.D3269= | Silent (SNP) | VAF 12/203 reads (6%) | called by muse, mutect2
- TCP11L1 | c.1302C>T p.P434= | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as rs375212322, COSV57517230; called by muse, mutect2, varscan2
- TENM3 | c.7821G>A p.V2607= | Silent (SNP) | VAF 26/142 reads (18%) | called by muse, mutect2, varscan2
- TIFAB | c.318C>G p.S106= | Silent (SNP) | VAF 113/380 reads (30%) | catalogued as COSV72345668; called by muse, mutect2, varscan2
- TP53 | c.795G>C p.L265= | Silent (SNP) | VAF 113/418 reads (27%) | catalogued as COSV52661636, COSV52730242, COSV52895662, COSV99474023; called by muse, mutect2, varscan2
- TPTE | c.1011C>T p.H337= (on ENST00000618007 / NM_199261.4; = p.H319= on NM_199259.4) | Silent (SNP) | VAF 23/236 reads (10%) | catalogued as rs549165021; called by muse, mutect2
- TRAF2 | c.804C>T p.L268= | Silent (SNP) | VAF 49/499 reads (10%) | called by muse, mutect2
- TRIML1 | c.288G>A p.G96= | Silent (SNP) | VAF 44/291 reads (15%) | called by muse, mutect2, varscan2
- TRMT12 | c.663C>T p.N221= | Silent (SNP) | VAF 70/447 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.14793C>T p.S4931= (on ENST00000591111; = p.S4004= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2
- TXNRD3 | c.87C>T p.R29= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as rs971894587; called by muse, mutect2, varscan2
- WNK2 | c.1248C>T p.A416= | Silent (SNP) | VAF 29/128 reads (23%) | called by muse, mutect2, varscan2
- XIRP2 | c.7332G>T p.R2444= (on ENST00000628543; = p.R2619= on NM_152381.6) | Silent (SNP) | VAF 32/179 reads (18%) | catalogued as COSV54684116; called by muse, mutect2, varscan2
- ZFYVE9 | c.810C>A p.I270= | Silent (SNP) | VAF 33/111 reads (30%) | called by muse, mutect2, varscan2
- ZMIZ2 | c.1020C>T p.G340= | Silent (SNP) | VAF 51/287 reads (18%) | catalogued as rs756330810, COSV54808632; called by muse, mutect2, varscan2
- AC004696.1 | chr19:56495078 G>T | 5'Flank (SNP) | VAF 17/128 reads (13%) | called by muse, mutect2, varscan2
- AC010507.1 | chr19:200767 C>T | 3'Flank (SNP) | VAF 3/233 reads (1%) | catalogued as rs752589210; called by muse, mutect2
- AC073310.1 | n.577T>C | RNA (SNP) | VAF 5/25 reads (20%) | catalogued as rs747242660; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73821558 C>T | 3'Flank (SNP) | VAF 32/176 reads (18%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73822545 C>A | 5'Flank (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73822546 C>A | 5'Flank (SNP) | VAF 19/73 reads (26%) | called by muse, mutect2, varscan2
- ANKRD45 | c.328+938A>G | Intron (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- AP2A1 | c.2115-159C>T | Intron (SNP) | VAF 61/251 reads (24%) | called by muse, mutect2, varscan2
- CHID1 | chr11:914595 G>T | 5'Flank (SNP) | VAF 25/126 reads (20%) | called by muse, mutect2, varscan2
- CLRN1 | c.254-3806G>C | Intron (SNP) | VAF 13/105 reads (12%) | called by muse, mutect2, varscan2
- COL1A1 | chr17:50180773 C>A | 3'Flank (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- CYP11B1 | c.239+145C>A | Intron (SNP) | VAF 64/438 reads (15%) | catalogued as COSV99455999; called by muse, mutect2, varscan2
- EDN2 | c.*38G>C | 3'UTR (SNP) | VAF 123/513 reads (24%) | catalogued as COSV101006339; called by muse, mutect2, varscan2
- EIF4G3 | c.-77G>A | 5'UTR (SNP) | VAF 14/174 reads (8%) | called by muse, mutect2
- FAM227B | c.441+349C>T | Intron (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- HACE1 | c.2514-31G>T | Intron (SNP) | VAF 17/121 reads (14%) | called by muse, mutect2
- IRGM | c.*19G>A | 3'UTR (SNP) | VAF 25/77 reads (32%) | called by muse, mutect2, varscan2
- L3MBTL1 | c.361-29C>T | Intron (SNP) | VAF 79/351 reads (23%) | catalogued as rs372007073; called by muse, mutect2, varscan2
- LINC00482 | n.1078G>C | RNA (SNP) | VAF 38/386 reads (10%) | called by muse, mutect2
- LMO2 | c.-272+493G>T | Intron (SNP) | VAF 35/177 reads (20%) | called by muse, mutect2, varscan2
- NBR1 | c.696-119G>A | Intron (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2
- NPDC1 | c.113-245A>G | Intron (SNP) | VAF 55/143 reads (38%) | catalogued as rs1413044099; called by muse, mutect2, varscan2
- NXF5 | n.596A>G | RNA (SNP) | VAF 39/185 reads (21%) | called by muse, mutect2, varscan2
- PIPSL | n.2538C>T | RNA (SNP) | VAF 41/487 reads (8%) | catalogued as rs879120270; called by muse, mutect2
- PSMD4 | c.964-210C>G | Intron (SNP) | VAF 21/258 reads (8%) | called by muse, mutect2
- RAB5C | c.-63G>T | 5'UTR (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.729T>C | RNA (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2
- SLC4A8 | c.131-33A>G | Intron (SNP) | VAF 21/179 reads (12%) | called by muse, mutect2, varscan2
- SLC6A8 | c.1496-21_1496-14del | Intron (DEL) | VAF 156/724 reads (22%) | called by mutect2, pindel, varscan2
- SPATA31C1 | n.3232G>A | RNA (SNP) | VAF 146/394 reads (37%) | called by muse, mutect2, varscan2
- SSU72 | chr1:1575163 T>G | 5'Flank (SNP) | VAF 53/468 reads (11%) | called by muse, mutect2, varscan2
- SYNE1 | c.25788+12G>A | Intron (SNP) | VAF 57/240 reads (24%) | called by muse, mutect2, varscan2
- TRIM51 | c.*1C>G | 3'UTR (SNP) | VAF 11/116 reads (9%) | catalogued as COSV99792296; called by muse, mutect2
- ZNF322P1 | n.558C>G | RNA (SNP) | VAF 6/21 reads (29%) | catalogued as rs1390784125; called by mutect2, varscan2
- ZNF878 | c.-1A>C | 5'UTR (SNP) | VAF 22/119 reads (18%) | called by muse, mutect2, varscan2
